Somatic mutation profile of tumor specimen MP2PRT-PAPCTZ-TMP1-A (aliquot MP2PRT-PAPCTZ-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPCTZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,732 days).
Specimen MP2PRT-PAPCTZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 285b17d1-8c66-4ab9-9eb7-56cd22badc7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPCTZ-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPCTZ-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/217a9282-e864-4e80-b599-6d05eb6eef32

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Splice Site 1, Missense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2533A>G p.R845G | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV54053469; called by muse, mutect2, varscan2
- PAX5 | c.1099+1G>T p.X367_splice | Splice Site (SNP) | VAF 88/337 reads (26%) | called by muse, mutect2, varscan2
- FEZ1 | c.243C>T p.T81= | Silent (SNP) | VAF 66/255 reads (26%) | catalogued as rs772450342, COSV54029881; called by muse, mutect2, varscan2
- SCN9A | c.5110C>T p.L1704= (on ENST00000303354; = p.L1693= on NM_002977.3) | Silent (SNP) | VAF 77/292 reads (26%) | catalogued as rs1214460947, COSV57604069; called by muse, mutect2, varscan2
- CD70 | chr19:6583311 C>T | 3'Flank (SNP) | VAF 52/192 reads (27%) | catalogued as rs769541158, COSV55567271; called by muse, mutect2, varscan2
